Somatic mutation profile of tumor specimen MP2PRT-PATZUN-TMP1-A (aliquot MP2PRT-PATZUN-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PATZUN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,301 days).
Specimen MP2PRT-PATZUN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f87c9d97-b507-4f8e-9600-5d7ab37e9502.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATZUN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATZUN-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91dab6d3-8f16-43ad-9b4d-13b02c6556cb

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Nonsense Mutation 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 87/246 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ITGB7 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1217596350; called by muse, mutect2, varscan2
- LRP4 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 156/424 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV101066832; called by muse, mutect2, varscan2
- MMS22L | c.3127G>T p.D1043Y | Missense Mutation (SNP) | VAF 29/432 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV51522211; called by muse, mutect2
- MUC16 | c.36673G>T p.A12225S | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.139); catalogued as rs761851478, COSV67479438; called by muse, mutect2, varscan2
- SPACA7 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 172/463 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs150944356; called by muse, mutect2, varscan2
- U2AF2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 218/483 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58272683; called by muse, mutect2, varscan2
- VSTM2B | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 187/540 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV59262272; called by muse, mutect2, varscan2
- ATM | c.973C>G p.H325D | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATP8A1 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 108/340 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- KBTBD6 | c.1631G>A p.W544* | Nonsense Mutation (SNP) | VAF 145/435 reads (33%) | called by muse, mutect2, varscan2
- MCOLN3 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 48/305 reads (16%) | called by muse, mutect2, varscan2
- NUDCD1 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 110/310 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- SF3A1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 99/281 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- IGKV3D-11 | c.346C>A p.*116= | Silent (SNP) | VAF 106/238 reads (45%) | called by muse, mutect2, varscan2
- NAV3 | c.2247G>A p.P749= | Silent (SNP) | VAF 62/511 reads (12%) | catalogued as rs367740483; called by muse, mutect2, varscan2
- PCDHB2 | c.1227G>A p.T409= | Silent (SNP) | VAF 163/371 reads (44%) | catalogued as rs891087855, COSV50576075; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823955 T>C | 5'Flank (SNP) | VAF 125/253 reads (49%) | called by muse, mutect2, varscan2
- REG3A | c.*41C>G | 3'UTR (SNP) | VAF 16/562 reads (3%) | called by muse, mutect2
